Gene-level copy-number profile of tumor specimen TARGET-10-PARMIH-09A from TARGET case TARGET-10-PARMIH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.4 years (4,537 days).
Specimen TARGET-10-PARMIH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.ebb47ba0-cd2f-5a25-964f-e66747d9d7f5.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PARMIH-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 355 have no estimate.
https://portal.gdc.cancer.gov/files/06d82be9-4efb-41d1-976a-b75e69c596ae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 2,485; copy number 2: 57,588; copy number 3: 172; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,601,086, 1 gene: LCE3C.
- chr7:38,273,587–38,335,514, 11 genes: TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7.
- chr9:21,966,929–21,995,301, 2 genes: CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,009,305, 2 genes: AL449423.1, CDKN2B.
- chr10:87,945,502–88,049,823, 3 genes: RPL11P3, AC063965.1, MED6P1.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:18,933,813–18,939,721, 2 genes, copy number 5: MRGPRX1, AC023078.1.

Autosomal genes at a single copy (total copy number 1): 105. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
